Somatic mutation profile of tumor specimen ASCProject_0097_T2_WES (aliquot ASCProject_0097_T2_WES_1) from CMI case ASCProject_0097, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 38.5 years (14,044 days).
Specimen ASCProject_0097_T2_WES: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Neck; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eca7ac55-4102-45d2-be28-e93a275c55c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0097_SALIVA_2 (Saliva), aliquot ASCProject_0097_SALIVA_2_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/162b89e7-cb10-42c6-8b78-98656bb6e9e6

The open-access MAF lists 69 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 14, Frame Shift Del 4, Intron 4, Nonsense Mutation 2, RNA 1, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL5 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.145); catalogued as rs747328031; called by muse, mutect2, varscan2
- ARHGAP8 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1187087068; called by muse, varscan2
- ARID1B | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as rs558155146, COSV51649102; called by muse, mutect2
- CENPJ | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.03); catalogued as rs142121392; called by mutect2, varscan2
- CMAS | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1040614577; called by muse, mutect2, varscan2
- COG1 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV55428516; called by muse, mutect2, varscan2
- CREM | c.332G>A p.R111H (on ENST00000429130; = p.R62H on NM_001881.3) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs759061714; called by mutect2, varscan2
- CSMD2 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs1436948628, COSV99586366; called by muse, mutect2, varscan2
- CSMD2 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs1330969566, COSV99586370; called by muse, mutect2, varscan2
- CUX1 | c.1532G>A p.R511H (on ENST00000437600 / NM_181500.4; = p.R513H on NM_001913.5) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs150151598; called by muse, mutect2, varscan2
- DROSHA | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60784626; called by muse, mutect2
- DUXA | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as rs371962814; called by muse, mutect2, varscan2
- GYS1 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.174); catalogued as rs1203781149; called by muse, mutect2, varscan2
- LMAN2 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as rs747269398, COSV57426136; called by muse, mutect2, varscan2
- LRRC71 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100503950; called by muse, varscan2
- MAN2A1 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.418); catalogued as rs375505532; called by muse, mutect2
- MATN3 | c.503C>G p.T168R | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as COSV68099761; called by muse, mutect2, varscan2
- MED26 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); catalogued as rs747499411, COSV99659901; called by mutect2, varscan2
- MUC4 | c.15694G>T p.V5232F (on ENST00000463781 / NM_018406.7; = p.V996F on NM_004532.6) | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as rs755720714; called by muse, mutect2, varscan2
- NAV2 | c.5480_5482del p.K1827del (on ENST00000396087 / NM_001244963.2; = p.K1771del on NM_145117.5) | In Frame Del (DEL) | VAF 3/37 reads (8%) | catalogued as rs777669469; called by mutect2, pindel
- NRCAM | c.2432C>T p.T811M (on ENST00000379028 / NM_001371124.1; = p.T795M on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766439513, COSV100694300; called by muse, mutect2, varscan2
- RASAL1 | c.1648G>T p.G550W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV99921594; called by muse, mutect2, varscan2
- USH1G | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746860881; called by muse, mutect2, varscan2
- ZNF280A | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as rs147857577, COSV104402512; called by mutect2, varscan2
- ZNF614 | c.1252C>G p.Q418E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV54545807; called by mutect2, varscan2
- ZRANB2 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs751149078; called by muse, varscan2
- ABCC4 | c.3748G>A p.G1250R | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD30B | c.3203A>T p.N1068I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CAMP | c.389A>T p.K130M (on ENST00000296435; = p.K127M on NM_004345.5) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, varscan2
- CEP78 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DENR | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2
- DEPDC5 | c.146+1G>A p.X49_splice | Splice Site (SNP) | VAF 4/33 reads (12%) | called by mutect2, varscan2
- FIZ1 | c.311A>G p.E104G | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FOXI1 | c.487_488del p.S163Qfs*41 | Frame Shift Del (DEL) | VAF 74/251 reads (29%) | called by pindel, varscan2
- GRIK2 | c.2394G>T p.W798C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLA-G | c.295A>G p.R99G | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HNRNPA0 | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- HSPB8 | c.500A>T p.E167V | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF4B | c.646T>A p.F216I | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO1F | c.216C>A p.D72E | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NHSL1 | c.676+5_676+8del | Splice Region (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- NLRP3 | c.822C>G p.I274M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- OR52I2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- POU5F2 | c.904_905del p.I302Pfs*55 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by pindel, varscan2
- SEMA4A | c.56del p.F19Sfs*51 | Frame Shift Del (DEL) | VAF 133/536 reads (25%) | called by mutect2, pindel, varscan2
- SPATA18 | c.1321_1354del p.Y441Nfs*14 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel
- TARM1 | c.472G>A p.D158N (on ENST00000616041 / NM_001330650.1; = p.D150N on NM_001135686.3) | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.018); called by muse, mutect2
- UNK | c.1699G>A p.G567S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR72 | c.334dup p.I112Nfs*29 | Frame Shift Ins (INS) | VAF 15/107 reads (14%) | called by mutect2, pindel, varscan2
- ZNF497 | c.821A>C p.H274P | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- C19orf54 | c.864G>C p.L288= | Silent (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- CTAGE15 | c.42G>C p.L14= | Silent (SNP) | VAF 43/201 reads (21%) | catalogued as rs747522011; called by muse, mutect2, varscan2
- FMR1NB | c.117G>A p.E39= | Silent (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- HIVEP1 | c.2430G>A p.P810= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs746339258; called by mutect2, varscan2
- HUNK | c.879C>T p.A293= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- LDHC | c.6A>C p.S2= | Silent (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2
- LRSAM1 | c.1152C>T p.D384= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs760074620; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCAPH | c.1803G>A p.Q601= | Silent (SNP) | VAF 40/202 reads (20%) | catalogued as rs377576873, COSV53635997; called by muse, mutect2, varscan2
- NPAS1 | c.1395G>T p.V465= | Silent (SNP) | VAF 53/476 reads (11%) | called by muse, mutect2, varscan2
- TAF1A | c.984G>A p.L328= | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- TENM2 | c.2502C>T p.G834= (on ENST00000518659 / NM_001122679.2; = p.G602= on NM_001080428.3) | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs374107882; called by mutect2, varscan2
- TRIM51GP | c.441A>G p.L147= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as rs1162373902; called by muse, mutect2
- WDR11 | c.3012A>G p.L1004= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs768066351; called by muse, mutect2, varscan2
- ZNF232 | c.801G>A p.Q267= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- AC104472.1 | n.240C>T | RNA (SNP) | VAF 6/48 reads (13%) | catalogued as rs930881140; called by muse, mutect2
- CNGA1 | c.-15+10490T>G | Intron (SNP) | VAF 6/37 reads (16%) | catalogued as rs1197725004, COSV104422602; called by muse, mutect2, varscan2
- GLP2R | c.1056+3802A>G | Intron (SNP) | VAF 17/106 reads (16%) | catalogued as rs1183343684; called by muse, mutect2, varscan2
- POFUT2 | c.528-451C>T | Intron (SNP) | VAF 4/40 reads (10%) | catalogued as rs759734845; called by mutect2, varscan2
- STK32B | c.108+305C>G | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
